BEATAML1.0 case 2085 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/8dd030bf-8094-4803-8f48-fdb292da31e1

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1: ICD-O-3 morphology code: 9896/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,512 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (8 samples)
- Samples BA2040D, BA2855D (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Samples BA2040R, BA2855R (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA2306R: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
- Sample BA2462D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA2842D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample BA2842R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
